Somatic mutation profile of tumor specimen TCGA-DA-A1HY-06A (aliquot TCGA-DA-A1HY-06A-11D-A19A-08) from TCGA case TCGA-DA-A1HY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.5 years (17,367 days).
Specimen TCGA-DA-A1HY-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1eff62ee-b8d7-4690-afd5-f1c64e5b9b11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1HY-10A (Blood Derived Normal), aliquot TCGA-DA-A1HY-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c9a9108-228d-4753-96b8-0cc0de65135d

The open-access MAF lists 874 somatic variants for this specimen: 578 protein-altering or splice-affecting, 281 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 525, Silent 281, Nonsense Mutation 33, Splice Region 9, Splice Site 7, RNA 5, Intron 5, Frame Shift Del 3, 3'UTR 3, Translation Start Site 1, 3'Flank 1, 5'Flank 1.

Variants (750 of 874; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2869C>T p.R957* | Nonsense Mutation (SNP) | VAF 26/40 reads (65%) | catalogued as rs121918440, CM981521, COSV55934187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A2ML1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV55299898; called by muse, mutect2, varscan2
- A4GNT | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 165/500 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV52630339; called by muse, mutect2, varscan2
- ABCA6 | c.3704C>T p.S1235F | Missense Mutation (SNP) | VAF 122/227 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1322663643, COSV52646517; called by muse, mutect2, varscan2
- ABCC3 | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 104/295 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53330880; called by muse, mutect2, varscan2
- AC097636.1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV101469686, COSV71309698; called by muse, mutect2, varscan2
- ACAN | c.4562G>A p.G1521E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61371108; called by muse, mutect2
- ACBD4 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1032685494, COSV58853835; called by muse, mutect2, varscan2
- ACOX1 | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV53137898; called by muse, mutect2, varscan2
- ACRV1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs183418543, COSV59755557; called by muse, mutect2, varscan2
- ACSBG1 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs867273879, COSV51906381; called by muse, mutect2, varscan2
- ACSL6 | c.1420G>A p.D474N (on ENST00000379240; = p.D499N on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs775219137, COSV57306564; called by muse, mutect2, varscan2
- ACSM3 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as rs267604444, COSV55504689; called by muse, mutect2, varscan2
- ADAMTS10 | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV54360411; called by muse, mutect2, varscan2
- ADAMTS12 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1341118014, COSV61258883, COSV61283550; called by muse, mutect2, varscan2
- ADAMTS18 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV51424450; called by muse, mutect2, varscan2
- ADCY8 | c.3124G>A p.A1042T | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53932339; called by muse, mutect2, varscan2
- ADGRE3 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53735839; called by muse, mutect2, varscan2
- ADGRF1 | c.2094G>A p.M698I | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV51948301; called by muse, mutect2, varscan2
- ADGRG5 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs766516943, COSV61084918; called by muse, mutect2, varscan2
- ADGRV1 | c.1828T>G p.F610V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67996904; called by muse, mutect2, varscan2
- ADORA3 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1439276880, COSV53987149; called by muse, mutect2, varscan2
- AHCY | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as rs772336831; called by muse, mutect2, varscan2
- AHCYL2 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61491862; called by muse, mutect2, varscan2
- AHNAK | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); catalogued as COSV57234612; called by muse, mutect2, varscan2
- AHRR | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs912194668, COSV57094945; called by muse, mutect2, varscan2
- AKAP11 | c.2733A>C p.L911F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV50304843; called by muse, varscan2
- AKAP13 | c.6745G>A p.E2249K (on ENST00000394518 / NM_007200.5; = p.E2253K on NM_006738.6) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV63471814; called by muse, mutect2, varscan2
- ALDH1A2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs778997757, COSV51092676; called by muse, mutect2, varscan2
- ALDH1L2 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV51560635; called by muse, mutect2, varscan2
- ALDH9A1 | c.1462+1G>A p.X488_splice | Splice Site (SNP) | VAF 31/37 reads (84%) | catalogued as rs140134210; called by muse, varscan2
- ALKBH4 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 74/103 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52962521; called by muse, mutect2, varscan2
- ANK3 | c.9169G>A p.G3057R | Missense Mutation (SNP) | VAF 77/146 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.231); catalogued as COSV55086537; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV51860758; called by muse, mutect2, varscan2
- ANKRD11 | c.5812C>T p.P1938S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1225667881, COSV56361405, COSV99968575; called by muse, mutect2, varscan2
- ANKRD30A | c.3595C>T p.H1199Y (on ENST00000611781; = p.H1143Y on NM_052997.2) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV64606158; called by muse, mutect2, varscan2
- ANKRD35 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.99); catalogued as COSV62911831; called by muse, mutect2, varscan2
- ANKS3 | c.251T>G p.I84S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58512358; called by muse, varscan2
- ANO4 | c.1993G>A p.E665K (on ENST00000392977 / NM_001286615.2; = p.E630K on NM_178826.4) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54596535; called by muse, mutect2, varscan2
- ANP32D | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56980220, COSV56980940; called by muse, mutect2, varscan2
- APLP1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.668); catalogued as rs1224573406, COSV55707503; called by muse, mutect2, varscan2
- APOB | c.11915G>A p.G3972E | Missense Mutation (SNP) | VAF 198/619 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV51946074; called by muse, mutect2, varscan2
- APP | c.2110G>A p.G704R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61006135; called by muse, mutect2, varscan2
- ARHGEF28 | c.4585G>A p.G1529S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV55273047; called by muse, mutect2, varscan2
- ARID3A | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55046941; called by muse, mutect2, varscan2
- ARL11 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs753334860, COSV56292190; called by muse, mutect2, varscan2
- ARMC4 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV53469166; called by muse, mutect2, varscan2
- ASB17 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV52410156; called by muse, mutect2, varscan2
- ASTN2 | c.2246C>T p.S749F (on ENST00000313400 / NM_001365069.1; = p.S698F on NM_014010.5) | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57800430, COSV57824160; called by muse, mutect2, varscan2
- ASTN2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV57755410; called by muse, mutect2, varscan2
- ASXL2 | c.3635C>T p.S1212L | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55469448; called by muse, mutect2, varscan2
- ATAD2B | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53206914, COSV99477816; called by muse, mutect2, varscan2
- ATE1 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.051); catalogued as COSV56444520; called by muse, mutect2, varscan2
- ATF2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs570902505, COSV51376791; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 108/189 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59475988; called by muse, mutect2, varscan2
- ATR | c.2910G>C p.M970I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV63393763; called by muse, mutect2, varscan2
- B3GALT2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66464638; called by muse, mutect2, varscan2
- BAAT | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200347226, COSV52287019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAM | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54304513, COSV54305601; called by muse, mutect2, varscan2
- BCAS4 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV52815332; called by muse, mutect2, varscan2
- BCR | c.3075C>T p.I1025= | Splice Region (SNP) | VAF 17/75 reads (23%) | catalogued as rs771658233, COSV59936558; called by muse, mutect2, varscan2
- BEST3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56994702, COSV56995769; called by muse, mutect2, varscan2
- BRD1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV53462564; called by muse, mutect2, varscan2
- BRD4 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54596341; called by muse, mutect2, varscan2
- BRD7 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs772928224, COSV67160307; called by muse, mutect2
- BRINP1 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56315597; called by muse, varscan2
- BRINP3 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1202690091, COSV66543986; called by muse, mutect2, varscan2
- BSND | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs749600956, COSV64871013; called by muse, mutect2, varscan2
- BSPRY | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs201176174; called by muse, mutect2, varscan2
- BTK | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 69/92 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM003419, COSV58124175; called by muse, mutect2, varscan2
- BTN1A1 | c.737G>A p.W246* | Nonsense Mutation (SNP) | VAF 81/224 reads (36%) | catalogued as rs144262313; called by muse, mutect2, varscan2
- C1orf94 | c.1030G>A p.E344K (on ENST00000488417 / NM_001134734.2; = p.E154K on NM_032884.5) | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as rs1297961791, COSV64916103; called by muse, mutect2, varscan2
- C4orf17 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as COSV58513210; called by muse, mutect2, varscan2
- C8B | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64778124; called by muse, mutect2, varscan2
- C8orf34 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV57410813; called by muse, mutect2, varscan2
- C9orf43 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55913556; called by muse, mutect2, varscan2
- CA3 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV53410551; called by muse, mutect2, varscan2
- CACNA1A | c.5448G>A p.M1816I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64214605; called by muse, mutect2
- CACNA1G | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61741897; called by muse, mutect2, varscan2
- CADM2 | c.598G>A p.A200T (on ENST00000407528 / NM_001167674.2; = p.A202T on NM_153184.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.342); catalogued as rs1333409387, COSV67375650; called by muse, mutect2, varscan2
- CARF | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 112/312 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57547322; called by muse, mutect2, varscan2
- CARS1 | c.1219A>G p.M407V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV53462252; called by muse, mutect2, varscan2
- CASR | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.153); catalogued as COSV56142179; called by muse, mutect2, varscan2
- CCDC14 | c.1234A>G p.I412V (on ENST00000488653; = p.I364V on NM_022757.5) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV59948571; called by muse, mutect2, varscan2
- CCDC85A | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV68156229; called by muse, mutect2, varscan2
- CCDC88A | c.3748C>T p.L1250= | Splice Region (SNP) | VAF 6/16 reads (38%) | catalogued as COSV55071375; called by muse, mutect2, varscan2
- CCER1 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs866835578, COSV62646213, COSV62647243; called by muse, mutect2, varscan2
- CD14 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100117545; called by muse, mutect2, varscan2
- CD1C | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV63805624; called by muse, mutect2, varscan2
- CDAN1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs751956841, COSV51184492; called by muse, mutect2, varscan2
- CDCA2 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV57949086; called by muse, mutect2, varscan2
- CDKN2A | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11552823, CM080133, COSV58683884, COSV58697231, COSV58717232; called by muse, mutect2, varscan2
- CEACAM20 | c.1614G>A p.T538= | Splice Region (SNP) | VAF 93/297 reads (31%) | catalogued as rs762179860, COSV57601271; called by muse, mutect2, varscan2
- CELSR3 | c.2980G>A p.G994S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51175764; called by muse, mutect2, varscan2
- CEP290 | c.6716T>C p.V2239A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV58357507; called by muse, mutect2, varscan2
- CES1 | c.1180G>A p.E394K (on ENST00000361503 / NM_001025194.2; = p.E393K on NM_001266.5) | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs777909006, COSV62090918; called by muse, mutect2, varscan2
- CHMP4C | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as rs1208893747, COSV51929332; called by muse, mutect2
- CHRNB3 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs746856425, COSV51495749; called by muse, mutect2, varscan2
- CHST11 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57996393; called by muse, mutect2, varscan2
- CILK1 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV63156402; called by muse, mutect2, varscan2
- CILP | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56026570; called by muse, mutect2, varscan2
- CNNM2 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV64002771; called by muse, mutect2, varscan2
- CNTN4 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.151); catalogued as rs759724901, COSV101281373, COSV68569064; called by muse, mutect2, varscan2
- COG4 | c.2155C>T p.L719F | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773267196, COSV55376200; called by muse, mutect2, varscan2
- COL14A1 | c.1691G>A p.G564D | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as rs866202010, COSV52871436; called by muse, mutect2, varscan2
- COL28A1 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68081409; called by muse, mutect2, varscan2
- COL3A1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.079); catalogued as rs1431670813, COSV58598107; called by muse, varscan2
- COL5A3 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs367847974; called by muse, mutect2
- COL6A6 | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs368734825, COSV100649980; called by muse, mutect2
- CPA1 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782136930, COSV50577170; called by muse, mutect2, varscan2
- CPN2 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV60472328; called by muse, mutect2, varscan2
- CR2 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65510190; called by muse, mutect2, varscan2
- CRNN | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 164/232 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV55120823, COSV55124360; called by muse, varscan2
- CTR9 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV100797503, COSV63729892; called by muse, mutect2, varscan2
- CUX1 | c.3229C>T p.P1077S | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV52919052; called by muse, mutect2, varscan2
- CYP21A2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 111/523 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1410365935, COSV64490672; called by muse, mutect2, varscan2
- CYP2C9 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV53250549; called by muse, mutect2, varscan2
- CYP2E1 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs761515989, COSV53315844; called by muse, mutect2, varscan2
- DAW1 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV59365121; called by muse, mutect2, varscan2
- DCC | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.061); catalogued as rs774540293, COSV59086280, COSV59109601; called by muse, mutect2, varscan2
- DCLK3 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373605259, COSV69363137; called by muse, mutect2, varscan2
- DDX60L | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV52723810; called by muse, mutect2
- DEPDC1 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV63959501; called by muse, mutect2, varscan2
- DGAT2L6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs369585641, COSV60717250; called by muse, mutect2, varscan2
- DIDO1 | c.5339C>G p.P1780R | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.612); catalogued as COSV56618884, COSV56635861; called by muse, mutect2, varscan2
- DIO2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs371030555; called by muse, mutect2, varscan2
- DIS3L2 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs745989142, COSV56054679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP3 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.878); catalogued as rs867239451, COSV52398867; called by muse, mutect2, varscan2
- DMBT1 | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs1202998169, COSV57566645; called by muse, mutect2
- DNAH11 | c.6655C>T p.H2219Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1387044605, COSV60986800; called by muse, mutect2, varscan2
- DNAH3 | c.6988G>A p.E2330K | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV54558188; called by muse, mutect2, varscan2
- DNAH5 | c.10864G>A p.E3622K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV54250560; called by muse, mutect2
- DNAH5 | c.5644G>A p.E1882K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs781193700, COSV54207867; called by muse, mutect2, varscan2
- DNAH6 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV52887386; called by muse, mutect2, varscan2
- DNAH7 | c.10195G>A p.E3399K | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV56765367; called by muse, mutect2, varscan2
- DNAH7 | c.4702G>A p.D1568N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as COSV56758034; called by muse, mutect2, varscan2
- DNAJC17 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV55026844; called by muse, mutect2, varscan2
- DNAJC18 | c.228G>A p.R76= | Splice Region (SNP) | VAF 31/58 reads (53%) | catalogued as rs779334608, COSV57417032; called by muse, mutect2, varscan2
- DOP1B | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV67696934; called by muse, mutect2, varscan2
- DPYSL5 | c.792G>A p.G264= | Splice Region (SNP) | VAF 45/120 reads (38%) | catalogued as COSV56517264; called by muse, mutect2, varscan2
- DRC7 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.596); catalogued as rs751832392, COSV100395329, COSV61058265; called by muse, mutect2, varscan2
- DSG3 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57127245, COSV57130325; called by muse, mutect2, varscan2
- DSP | c.3718G>A p.D1240N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV65796807; called by muse, mutect2, varscan2
- DUOXA2 | c.899T>G p.L300R | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV50995139; called by muse, mutect2, varscan2
- DUSP22 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.129); catalogued as rs1469443817, COSV60530939; called by muse, mutect2, varscan2
- DYSF | c.1929C>G p.D643E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50282226, COSV50642791; called by muse, mutect2, varscan2
- DYSF | c.2944C>T p.P982S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.99); catalogued as rs761004535, COSV50642973; called by muse, mutect2, varscan2
- DZIP1 | c.1660G>A p.E554K (on ENST00000347108; = p.E535K on NM_014934.5) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV61270960; called by muse, mutect2, varscan2
- ECE1 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs144860890; called by muse, mutect2, varscan2
- EEPD1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54197788; called by muse, mutect2, varscan2
- EFCAB6 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV53074560; called by muse, mutect2, varscan2
- ELAVL2 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56372879; called by muse, mutect2
- EMSY | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58266916; called by muse, mutect2, varscan2
- ENAM | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV68536420; called by mutect2, varscan2
- EPAS1 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55391043; called by muse, mutect2, varscan2
- EPC2 | c.788A>T p.H263L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51550349; called by muse, mutect2, varscan2
- EXD1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.598); catalogued as COSV59255234; called by muse, mutect2, varscan2
- EXOSC10 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as COSV58668619; called by muse, mutect2, varscan2
- EXTL3 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.565); catalogued as COSV55040918; called by muse, mutect2, varscan2
- F11R | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT tolerated (0.12); PolyPhen benign (0.141); catalogued as rs144466757; called by muse, mutect2, varscan2
- FADS3 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53880847; called by muse, mutect2, varscan2
- FAM110C | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV59655734; called by muse, mutect2, varscan2
- FANCD2 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55048005; called by muse, mutect2
- FCRL3 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63840285; called by muse, mutect2, varscan2
- FGF12 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1451755188, COSV53192719; called by muse, mutect2, varscan2
- FILIP1L | c.1034G>A p.R345Q (on ENST00000354552 / NM_182909.3; = p.R105Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0.13); catalogued as rs374961168; called by muse, mutect2, varscan2
- FKBP5 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV61884288; called by muse, mutect2, varscan2
- FLG | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV100912211, COSV64251639; called by muse, mutect2, varscan2
- FLT3 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54073792; called by muse, mutect2, varscan2
- FMO3 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs775749562, CM129718, COSV63007211; called by muse, mutect2, varscan2
- FMO3 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768393243, COSV63007308; called by muse, mutect2, varscan2
- FMO5 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54211346; called by muse, mutect2, varscan2
- GAB4 | c.1135T>C p.S379P | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV68755429; called by muse, mutect2, varscan2
- GABBR2 | c.2011G>C p.G671R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1414145, COSV52322492; called by muse, mutect2, varscan2
- GABRA2 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV62914098; called by muse, mutect2, varscan2
- GABRA2 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100734590, COSV62911664; called by muse, varscan2
- GALNT13 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV67242495; called by muse, mutect2, varscan2
- GANAB | c.1664C>T p.T555I | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV60469321; called by muse, mutect2, varscan2
- GBA2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV62306886; called by muse, mutect2, varscan2
- GJB4 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58355602; called by muse, mutect2, varscan2
- GLB1 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56568735; called by muse, mutect2, varscan2
- GPR37L1 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 78/92 reads (85%) | catalogued as COSV66162910; called by muse, mutect2, varscan2
- GPR84 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV57210560; called by muse, mutect2, varscan2
- GRAMD1C | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs866613409, COSV63982781; called by muse, mutect2, varscan2
- GRIN2B | c.2657C>T p.S886F | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV74208355; called by muse, mutect2, varscan2
- GRM8 | c.799A>C p.K267Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV58878675; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 32/67 reads (48%) | catalogued as COSV100736415; called by mutect2, varscan2
- HAPLN3 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61371113; called by muse, mutect2, varscan2
- HDLBP | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV60501992; called by muse, mutect2, varscan2
- HEATR6 | c.248G>C p.C83S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV51749666; called by muse, mutect2, varscan2
- HECTD4 | c.11965C>T p.R3989* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as rs1261555593, COSV66394110; called by muse, mutect2, varscan2
- HEPHL1 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59894892; called by muse, mutect2, varscan2
- HHIP | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.575); catalogued as rs149139999, COSV56837577; called by muse, mutect2, varscan2
- HIP1R | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53445576; called by muse, mutect2
- HIVEP2 | c.4655C>T p.P1552L | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs369123442; called by muse, mutect2, varscan2
- HIVEP3 | c.5081T>C p.V1694A | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV56025585; called by muse, mutect2, varscan2
- HJURP | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV64979704; called by muse, mutect2
- HJURP | c.2034C>G p.F678L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV64979707; called by muse, mutect2
- HP1BP3 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56565135; called by muse, mutect2
- HPS3 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56057945; called by muse, mutect2, varscan2
- HSPA12A | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65021044; called by muse, mutect2, varscan2
- HYAL4 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56140691; called by muse, mutect2, varscan2
- ICAM4 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53427695; called by muse, mutect2, varscan2
- IGF1 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 107/334 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV61033153, COSV61035284; called by muse, mutect2, varscan2
- IGSF9 | c.2798G>A p.R933Q (on ENST00000368094 / NM_001135050.2; = p.R917Q on NM_020789.4) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as rs1051809154, COSV57423983; called by muse, mutect2, varscan2
- INPP5D | c.1556G>A p.G519E (on ENST00000445964 / NM_001017915.3; = p.G518E on NM_005541.5) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.492); catalogued as rs1198438745, COSV64040625; called by muse, mutect2
- INSRR | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63877959; called by muse, mutect2, varscan2
- IPCEF1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 53/78 reads (68%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV54552607; called by muse, mutect2, varscan2
- IQSEC3 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.301); catalogued as COSV58292248; called by muse, mutect2, varscan2
- ITGA11 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as COSV59882815; called by muse, mutect2, varscan2
- IVL | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.136); catalogued as COSV64217409; called by muse, mutect2
- KBTBD3 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73241661; called by muse, mutect2, varscan2
- KBTBD8 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs149863845; called by muse, mutect2, varscan2
- KCNH5 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59779036; called by muse, mutect2, varscan2
- KCNQ3 | c.1988C>T p.T663I | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.121); catalogued as COSV66484183; called by muse, mutect2, varscan2
- KCNU1 | c.2602C>T p.P868S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.536); catalogued as COSV67760513; called by muse, mutect2, varscan2
- KDF1 | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV57672362; called by muse, mutect2, varscan2
- KDM3B | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs1230415816, COSV58695929; called by muse, mutect2, varscan2
- KDM5D | c.2846C>T p.S949F | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV58737391; called by muse, mutect2, varscan2
- KDR | c.3806T>A p.L1269Q | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV55778329; called by muse, mutect2, varscan2
- KLB | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57305796; called by muse, mutect2, varscan2
- KLHDC10 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59054460; called by muse, mutect2, varscan2
- KLHL10 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53175412; called by muse, mutect2, varscan2
- KMT2A | c.4219-2A>G p.X1407_splice | Splice Site (SNP) | VAF 26/58 reads (45%) | catalogued as COSV63293614; called by muse, mutect2, varscan2
- KRBA1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55444869; called by muse, mutect2, varscan2
- KRT40 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66697247; called by muse, mutect2
- KRT75 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52874629; called by muse, mutect2, varscan2
- KRT80 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57552238; called by muse, mutect2, varscan2
- KRTAP5-1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as COSV66299388; called by mutect2, varscan2
- KRTDAP | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); catalogued as rs758534859, COSV58865823; called by muse, mutect2, varscan2
- LARGE2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.18); catalogued as COSV57686843; called by muse, mutect2, varscan2
- LARS1 | c.3385C>T p.P1129S (on ENST00000394434 / NM_020117.11; = p.P1102S on NM_016460.3) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs765125271, COSV50995456; called by mutect2, varscan2
- LCMT1 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs755695509, COSV66726365; called by muse, mutect2, varscan2
- LDB3 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53951259; called by muse, mutect2, varscan2
- LGI1 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs747229730, COSV65058941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LILRA1 | c.674A>T p.K225M | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52186038; called by muse, mutect2, varscan2
- LIN28B | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100558466, COSV61498275; called by muse, mutect2, varscan2
- LRP1B | c.6113G>A p.G2038E | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as rs1190814401, COSV67198055, COSV67283725; called by muse, mutect2, varscan2
- LRP1B | c.3320G>A p.G1107E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67284288; called by muse, mutect2, varscan2
- LRRC4C | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53440532; called by muse, mutect2, varscan2
- LRRIQ3 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 85/109 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV63041391; called by muse, mutect2, varscan2
- LRRIQ3 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV63051210; called by muse, mutect2, varscan2
- LRRTM1 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV54447802; called by muse, mutect2, varscan2
- LY96 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV53027109; called by muse, mutect2, varscan2
- MAGEA11 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV60759284; called by muse, mutect2, varscan2
- MAGT1 | c.218C>T p.S73F (on ENST00000618282 / NM_001367916.1; = p.S105F on NM_032121.5) | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868965086, COSV63780945; called by muse, mutect2, varscan2
- MAP3K13 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.996); catalogued as COSV53984557, COSV53991953; called by muse, mutect2, varscan2
- MAP3K21 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs767244768, COSV64042912; called by muse, mutect2, varscan2
- MARCHF7 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as rs781070967, COSV52032035; called by muse, mutect2, varscan2
- MARCO | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748644550, COSV59053393; called by muse, mutect2, varscan2
- MCF2L | c.2239T>G p.F747V (on ENST00000375608; = p.F715V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56182797; called by muse, mutect2, varscan2
- MCM2 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 65/148 reads (44%) | catalogued as COSV54038094; called by muse, mutect2, varscan2
- MED12L | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as rs903557574, COSV56388312; called by muse, mutect2, varscan2
- MED16 | c.1174C>T p.H392Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1311720650; called by muse, mutect2, varscan2
- METTL21C | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV57433928; called by muse, mutect2, varscan2
- METTL8 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.311); catalogued as COSV64552335; called by muse, mutect2, varscan2
- MFSD4A | c.975+1G>A p.X325_splice | Splice Site (SNP) | VAF 22/71 reads (31%) | catalogued as COSV65657203; called by muse, mutect2, varscan2
- MGAM | c.2611C>T p.L871F | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV72074843, COSV72076111; called by muse, mutect2, varscan2
- MGAT5B | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56938138; called by muse, mutect2, varscan2
- MMP16 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs768109261, COSV54176168; called by muse, mutect2, varscan2
- MMP20 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52778942; called by muse, mutect2, varscan2
- MON2 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV54816818; called by muse, mutect2, varscan2
- MORC1 | c.2103G>A p.M701I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51723260; called by muse, mutect2
- MORC3 | c.2798T>C p.M933T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV68689552; called by muse, mutect2, varscan2
- MPHOSPH8 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV64058157; called by muse, mutect2, varscan2
- MRC2 | c.3310G>A p.G1104S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57645439; called by muse, mutect2, varscan2
- MRPL19 | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62566706, COSV62568290; called by muse, mutect2, varscan2
- MTMR12 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs779217202, COSV53788886; called by muse, mutect2, varscan2
- MUC16 | c.43211G>A p.R14404K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.04); catalogued as COSV66697495; called by muse, mutect2, varscan2
- MUC16 | c.21106C>T p.P7036S | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1245163345, COSV67477246; called by muse, mutect2, varscan2
- MUC16 | c.15854C>T p.P5285L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as COSV67470399, COSV67500869; called by muse, mutect2, varscan2
- MUC16 | c.14233C>T p.P4745S | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as COSV67500880; called by muse, mutect2, varscan2
- MUC16 | c.6445G>A p.A2149T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1231866669, COSV67500901; called by muse, mutect2, varscan2
- MUC16 | c.4964C>T p.S1655F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67500908; called by muse, mutect2, varscan2
- MUC16 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV67481354, COSV67496641; called by muse, mutect2, varscan2
- MUC16 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); catalogued as rs572848181, COSV67500921; called by muse, mutect2, varscan2
- MUC17 | c.9640A>G p.T3214A | Missense Mutation (SNP) | VAF 229/407 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); catalogued as COSV60307008; called by muse, mutect2, varscan2
- MXRA5 | c.6652G>A p.D2218N | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV54254156; called by muse, mutect2, varscan2
- MXRA5 | c.3209G>A p.G1070E | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54235560; called by muse, mutect2, varscan2
- MYH7 | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV62519905; called by muse, mutect2, varscan2
- MYLK | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.267); catalogued as COSV60624779; called by muse, mutect2, varscan2
- MYO15A | c.3560C>T p.S1187F | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52768240; called by muse, mutect2, varscan2
- MYO16 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1200275190, COSV51779265; called by muse, mutect2, varscan2
- MYO5B | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV53233740; called by muse, mutect2, varscan2
- MYO7B | c.4189G>A p.V1397M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1022726693, COSV67352900; called by muse, mutect2, varscan2
- MYO9A | c.3239T>C p.L1080P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.659); catalogued as COSV61859986; called by muse, mutect2, varscan2
- MYOF | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs1395148896, COSV63711851; called by muse, mutect2, varscan2
- MYORG | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as rs1454379408, COSV52628872; called by muse, mutect2, varscan2
- NAV3 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs775456605, COSV57078632; called by muse, mutect2, varscan2
- NCKAP5 | c.3234G>A p.M1078I | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58480251; called by muse, mutect2, varscan2
- NCKAP5 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58436740; called by muse, mutect2, varscan2
- NCOR2 | c.6106C>T p.R2036C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs763480105; called by muse, mutect2, varscan2
- NDNF | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs770226517, COSV65634960; called by muse, mutect2, varscan2
- NDUFAF6 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 96/219 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV54411269; called by muse, mutect2, varscan2
- NEBL | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV65802012; called by muse, mutect2, varscan2
- NEFM | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV55333926, COSV55335491; called by muse, mutect2, varscan2
- NELL1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV54336614; called by muse, mutect2, varscan2
- NEUROD1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 139/484 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV54550074; called by muse, mutect2, varscan2
- NIPAL1 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55007972; called by muse, mutect2, varscan2
- NLRP13 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as rs372299456; called by muse, mutect2, varscan2
- NLRP8 | c.1674C>A p.F558L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52595244; called by muse, mutect2, varscan2
- NODAL | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV54662867; called by muse, mutect2, varscan2
- NOTCH4 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.13); catalogued as rs773175586, COSV66684554; called by muse, mutect2, varscan2
- NPSR1 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as COSV62207254; called by muse, mutect2, varscan2
- NSMCE2 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs201930510, COSV54896410; called by muse, mutect2, varscan2
- NXPH1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68314477; called by muse, mutect2, varscan2
- OR12D3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs760362736, COSV65828517; called by muse, mutect2, varscan2
- OR1J2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs376034267; called by muse, mutect2, varscan2
- OR1M1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.123); catalogued as COSV70036965; called by muse, mutect2, varscan2
- OR1N2 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.069); catalogued as COSV65461364; called by muse, mutect2, varscan2
- OR2A25 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV68717554; called by muse, mutect2, varscan2
- OR2C1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV59241563; called by muse, mutect2, varscan2
- OR2M2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 162/316 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV62897957; called by muse, mutect2, varscan2
- OR2M4 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV60707151, COSV60710017; called by muse, mutect2, varscan2
- OR2S2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV59531545; called by muse, mutect2, varscan2
- OR2W3 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.443); catalogued as rs763409297, COSV64457166, COSV64458281; called by muse, mutect2, varscan2
- OR2Z1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as rs782472476, COSV60691691; called by muse, mutect2, varscan2
- OR4C16 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1565052193, COSV58942866; called by muse, mutect2, varscan2
- OR4K5 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60004999, COSV60005613; called by muse, mutect2, varscan2
- OR4X1 | c.452T>G p.L151R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60724250; called by muse, mutect2, varscan2
- OR52M1 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs746994385, COSV64172713; called by muse, mutect2, varscan2
- OR5T2 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs766855910, COSV57589018, COSV57590753; called by muse, mutect2, varscan2
- OR6B3 | c.967C>A p.H323N | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV60116888; called by muse, mutect2, varscan2
- OR6C70 | c.856T>A p.F286I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs1454496755, COSV59244988, COSV59245546; called by muse, mutect2, varscan2
- OR6C76 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as rs763766119, COSV60388888; called by muse, mutect2, varscan2
- OR9Q2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs751860372, COSV61112967; called by muse, mutect2, varscan2
- OTUD7A | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100193461, COSV61044373; called by muse, mutect2, varscan2
- OXR1 | c.1213G>A p.E405K (on ENST00000442977 / NM_001198532.1; = p.E404K on NM_018002.3) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs1341095797, COSV56337804; called by muse, mutect2, varscan2
- P4HA3 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV59044462; called by muse, mutect2, varscan2
- PADI2 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751133296, COSV64953550; called by muse, mutect2, varscan2
- PALB2 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55171070; called by muse, mutect2, varscan2
- PAPPA | c.3932C>T p.S1311F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as COSV100073746, COSV60277105; called by muse, mutect2, varscan2
- PARP4 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551789119; called by muse, mutect2, varscan2
- PATJ | c.4393C>T p.H1465Y | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV57158089; called by muse, mutect2, varscan2
- PATZ1 | c.1961C>T p.S654F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56744471, COSV56744774; called by muse, mutect2, varscan2
- PCCA | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66157849; called by muse, mutect2, varscan2
- PCDH15 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.426); catalogued as rs747154146, COSV57374587; called by muse, mutect2, varscan2
- PCDH15 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV57409812; called by muse, mutect2, varscan2
- PCDH18 | c.2716C>T p.L906F | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV61272775; called by muse, mutect2, varscan2
- PCDH19 | c.2686T>C p.F896L (on ENST00000373034 / NM_001184880.2; = p.F848L on NM_020766.3) | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV55273177; called by muse, mutect2, varscan2
- PCDHA11 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56480358, COSV56484098; called by muse, mutect2, varscan2
- PCDHAC2 | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs782755782, COSV53874206; called by muse, mutect2, varscan2
- PCDHB11 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs782536109, COSV61309676; called by muse, mutect2, varscan2
- PCDHB14 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53391836; called by muse, mutect2, varscan2
- PCDHB16 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53372629; called by muse, mutect2, varscan2
- PCDHB8 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); catalogued as COSV50828977; called by muse, mutect2
- PCDHB8 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs148140727, COSV50755144; called by muse, mutect2, varscan2
- PCDHGA5 | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV54051555; called by muse, mutect2, varscan2
- PCDHGA5 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV54051578; called by muse, mutect2, varscan2
- PCDHGB1 | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as rs764844897, COSV54051537; called by muse, mutect2, varscan2
- PCLO | c.14516C>T p.S4839F | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61675521; called by muse, mutect2, varscan2
- PCLO | c.6098C>T p.S2033F | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs938415119, COSV61618905; called by muse, mutect2, varscan2
- PCNA | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as COSV64770857; called by muse, mutect2, varscan2
- PCSK9 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 146/522 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs1553135931, COSV56163842; ClinVar: benign; called by muse, mutect2, varscan2
- PDE1C | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 166/299 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1231777861, COSV58516426, COSV58529809; called by muse, mutect2, varscan2
- PDE1C | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as COSV68820548; called by muse, mutect2, varscan2
- PDGFD | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56368858, COSV56380199; called by muse, mutect2, varscan2
- PEBP4 | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs1477507621, COSV56473159; called by muse, mutect2, varscan2
- PGAP2 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV53468096; called by muse, mutect2, varscan2
- PHF20 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.021); catalogued as COSV59189770; called by muse, mutect2, varscan2
- PHLDB1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV61882401; called by muse, mutect2, varscan2
- PHLDB2 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs759554814, COSV67313091, COSV67316762; called by muse, mutect2, varscan2
- PID1 | c.409G>A p.E137K (on ENST00000354069 / NM_001330156.1; = p.E135K on NM_017933.5) | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as rs868310857, COSV62481739; called by muse, mutect2, varscan2
- PIGN | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62952256; called by muse, mutect2, varscan2
- PIK3CG | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV63253172, COSV63253378; called by muse, mutect2, varscan2
- PKD1L1 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1294890107, COSV56980403; called by muse, mutect2, varscan2
- PKHD1 | c.4373C>T p.S1458F | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs1166012817, COSV61898028; called by muse, mutect2
- PKHD1L1 | c.5557G>A p.G1853R | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65755638; called by muse, mutect2, varscan2
- PKHD1L1 | c.12473C>T p.P4158L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV101006806, COSV65755644; called by muse, mutect2, varscan2
- PKP1 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1558193245, COSV55826167; called by muse, mutect2, varscan2
- PLEKHG1 | c.3643A>G p.R1215G | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV62051854; called by muse, mutect2, varscan2
- PLEKHG4B | c.3153G>A p.K1051= (on ENST00000283426; = p.K1407= on NM_052909.5) | Splice Region (SNP) | VAF 19/52 reads (37%) | catalogued as rs780976965, COSV52056799; called by muse, mutect2, varscan2
- PLEKHG4B | c.3721G>A p.E1241K (on ENST00000283426; = p.E1597K on NM_052909.5) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV52046628; called by muse, mutect2, varscan2
- PLEKHN1 | c.1544C>T p.P515L (on ENST00000379409; = p.P463L on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV58024152; called by muse, mutect2, varscan2
- PLIN4 | c.466G>A p.D156N (on ENST00000301286; = p.D171N on NM_001367868.2) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV56698068; called by muse, mutect2, varscan2
- PLPPR5 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1227771809; called by muse, mutect2, varscan2
- PLXDC1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV59554333; called by muse, mutect2, varscan2
- PLXNA4 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV58166068; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV62613904; called by muse, mutect2, varscan2
- POLR2B | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs376895637; called by muse, mutect2, varscan2
- POU2AF1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV67577902; called by muse, mutect2, varscan2
- POU6F2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs775326639, COSV68872282; called by muse, mutect2, varscan2
- PPIG | c.2011C>T p.H671Y | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs867147669, COSV53646871; called by muse, mutect2, varscan2
- PPP1R13L | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV62910009; called by muse, mutect2, varscan2
- PPP1R21 | c.99T>G p.D33E | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as COSV54290432; called by muse, mutect2, varscan2
- PPP4R4 | c.1428+1G>A p.X476_splice | Splice Site (SNP) | VAF 34/57 reads (60%) | catalogued as COSV58559192; called by muse, mutect2, varscan2
- PRB3 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.839); catalogued as COSV54394088; called by muse, varscan2
- PREX2 | c.2702C>T p.S901F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV55771253; called by muse, mutect2, varscan2
- PRKAG2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs939188161, COSV55243844; called by muse, mutect2
- PRKDC | c.7649T>C p.I2550T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.057); catalogued as rs373258150, COSV58066702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR22 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57833943; called by muse, mutect2, varscan2
- PRR3 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV64835631; called by muse, mutect2, varscan2
- PSAPL1 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV59844803; called by muse, mutect2
- PXDNL | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1049626878, COSV62493530; called by muse, mutect2, varscan2
- RAB18 | c.262T>C p.Y88H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63614108; called by muse, mutect2, varscan2
- RAB6C | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV101308494; called by muse, mutect2, varscan2
- RALYL | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV72826677; called by muse, mutect2, varscan2
- RANGAP1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs767290351, COSV62365045; called by muse, mutect2, varscan2
- RBL1 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as rs1394691517, COSV60334578; called by muse, mutect2, varscan2
- RBM6 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs759507731, COSV56489163; called by muse, mutect2
- RELN | c.4226C>T p.S1409F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59039145; called by muse, mutect2, varscan2
- RGL4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs371757094; called by muse, mutect2, varscan2
- RIPK4 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60186497; called by muse, mutect2, varscan2
- RIPOR3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50409117; called by muse, mutect2, varscan2
- RNF113B | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57436370; called by muse, mutect2, varscan2
- RORB | c.1106A>C p.E369A (on ENST00000396204 / NM_001365023.1; = p.E358A on NM_006914.4) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV65340834; called by muse, mutect2, varscan2
- RSBN1 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV54734307; called by muse, mutect2, varscan2
- RUNDC3B | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV56697864; called by muse, mutect2, varscan2
- RYR2 | c.12409G>A p.E4137K | Missense Mutation (SNP) | VAF 82/98 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598439, COSV63666259; called by muse, mutect2, varscan2
- SAE1 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV54299675; called by muse, mutect2, varscan2
- SALL2 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV58106336; called by muse, mutect2, varscan2
- SAMD12 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV59046385; called by muse, mutect2, varscan2
- SAMD9L | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 101/166 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59086082; called by muse, mutect2, varscan2
- SCARA5 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051572545, COSV61571333, COSV61572017; called by muse, mutect2, varscan2
- SCEL | c.1319G>A p.R440K (on ENST00000349847 / NM_144777.3; = p.R420K on NM_003843.4) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV62994760; called by muse, mutect2, varscan2
- SCN1A | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs531894715, CM113266, COSV57674217; called by muse, mutect2, varscan2
- SCNN1B | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100225882, COSV56311335; called by muse, mutect2, varscan2
- SDR42E1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs531813448, COSV61095238; called by muse, mutect2, varscan2
- SEC14L4 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV55400958, COSV55401094; called by muse, mutect2, varscan2
- SEC14L4 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1353183466, COSV55401974; called by muse, mutect2
- SEC14L5 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV52038034, COSV99229509; called by muse, mutect2, varscan2
- SEMA4G | c.2426G>A p.G809E (on ENST00000370250; = p.G814E on NM_017893.3) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as rs921452117, COSV52972804; called by muse, mutect2, varscan2
- SEPTIN4 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.222); catalogued as COSV58729255; called by muse, mutect2, varscan2
- SERPINA10 | c.720G>A p.G240= | Splice Region (SNP) | VAF 21/39 reads (54%) | catalogued as rs1338744369, COSV56229994; called by muse, mutect2, varscan2
- SERPINA11 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1366468410, COSV58243595; called by mutect2, varscan2
- SEZ6L | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV50686136; called by muse, mutect2, varscan2
- SH3RF1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.914); catalogued as COSV52926051; called by muse, mutect2, varscan2
- SHOX | c.207T>A p.H69Q | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV61862618; called by muse, mutect2, varscan2
- SHROOM2 | c.3986C>T p.S1329F | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771863378, COSV66611298; called by muse, mutect2, varscan2
- SIGIRR | c.481+1G>A p.X161_splice | Splice Site (SNP) | VAF 27/79 reads (34%) | catalogued as COSV58990515; called by muse, mutect2, varscan2
- SIGLEC7 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs377355598; called by muse, mutect2, varscan2
- SKIV2L | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 160/456 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64814767; called by muse, mutect2, varscan2
- SKIV2L | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 178/468 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1562654402, COSV64814775; called by muse, mutect2, varscan2
- SLC10A2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs1325389584, COSV55361015, COSV55362212; called by muse, mutect2, varscan2
- SLC16A1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs773937509, COSV63710562; called by muse, mutect2, varscan2
- SLC25A31 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55418092; called by muse, mutect2, varscan2
- SLC38A1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.147); catalogued as rs267603474, COSV67065149; called by muse, mutect2, varscan2
- SLC38A10 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs747278374, COSV55849984; called by muse, mutect2, varscan2
- SLC5A6 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs771862888, COSV60161756; called by muse, mutect2, varscan2
- SLIT2 | c.4499G>A p.R1500Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs766242125, COSV56564759; called by muse, mutect2, varscan2
- SLIT3 | c.2449C>T p.H817Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100265328; called by muse, mutect2, varscan2
- SMU1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV68139626; called by muse, mutect2, varscan2
- SNX19 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV56283728; called by muse, mutect2, varscan2
- SP140 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.354); catalogued as COSV59456048; called by muse, mutect2, varscan2
- SP140L | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV54741128; called by muse, mutect2, varscan2
- SPARCL1 | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs143716987; called by muse, mutect2, varscan2
- SPARCL1 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56806684; called by muse, mutect2, varscan2
- SPEG | c.7792G>A p.G2598R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56681645; called by muse, mutect2, varscan2
- SPOCK3 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759137530, COSV62737072; called by muse, mutect2
- SPTA1 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 49/150 reads (33%) | catalogued as rs757845058, COSV63760797; called by muse, mutect2, varscan2
- SRCAP | c.5590G>A p.A1864T | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV52682649; called by muse, mutect2, varscan2
- SRD5A1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as rs751565473, COSV52957612; called by muse, mutect2, varscan2
- STT3B | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV55506589; called by muse, mutect2, varscan2
- SUCNR1 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780228673, COSV62912915; called by muse, mutect2, varscan2
- SYNDIG1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs987447091, COSV65239788; called by muse, mutect2, varscan2
- SYNPO2 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61119244; called by muse, mutect2, varscan2
- SYT7 | c.136-1G>A p.X46_splice | Splice Site (SNP) | VAF 25/75 reads (33%) | catalogued as COSV55660216; called by muse, mutect2, varscan2
- TACR3 | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV59209870; called by muse, mutect2, varscan2
- TAL1 | c.31C>A p.R11S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV53749215; called by muse, mutect2, varscan2
- TAOK2 | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as COSV54242101; called by muse, mutect2, varscan2
- TAP2 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as COSV66500998; called by muse, mutect2, varscan2
- TCTN3 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as COSV56450897; called by muse, mutect2, varscan2
- TEC | c.1589A>G p.K530R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV51920364; called by muse, mutect2, varscan2
- TENM4 | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53679253; called by muse, mutect2, varscan2
- THEM5 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV64313317; called by muse, mutect2, varscan2
- THOP1 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57021592; called by muse, mutect2
- THRA | c.813C>A p.S271R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.414); catalogued as COSV52846950; called by muse, mutect2, varscan2
- TIPARP | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | catalogued as COSV55815969; called by muse, mutect2, varscan2
- TMC3 | c.1715G>A p.W572* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as COSV63924867; called by muse, varscan2
- TMC3 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV63924871; called by muse, mutect2
- TMC7 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1215634897, COSV58588559; called by muse, mutect2, varscan2
- TMEM19 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57001442; called by muse, mutect2, varscan2
- TMEM72 | c.453C>G p.D151E | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV67461382; called by muse, mutect2, varscan2
- TNFRSF8 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs140319459; called by muse, mutect2, varscan2
- TNPO1 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 46/108 reads (43%) | catalogued as COSV61524464; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62627445; called by muse, mutect2, varscan2
- TP53BP1 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.997); catalogued as COSV55511298; called by muse, mutect2, varscan2
- TPP2 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV65755271; called by muse, mutect2, varscan2
- TPTE | c.583C>T p.R195* (on ENST00000618007 / NM_199261.4; = p.R177* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs775040644; called by muse, mutect2, varscan2
- TRANK1 | c.6991G>A p.G2331R | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as COSV57166735; called by muse, mutect2, varscan2
- TRHDE | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754939184, COSV53870139; called by muse, mutect2, varscan2
- TRHR | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61237025; called by muse, mutect2, varscan2
- TRIM51 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs1364427879, COSV55271792; called by muse, mutect2, varscan2
- TRIM56 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as rs1164210525, COSV60161808; called by muse, mutect2, varscan2
- TRPM1 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56644230; called by muse, mutect2, varscan2
- TRPM1 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM097736, COSV56635763; called by muse, mutect2, varscan2
- TRPM8 | c.3034C>T p.P1012S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs559620311, COSV61221877; called by muse, mutect2
- TRRAP | c.7585G>A p.D2529N (on ENST00000359863 / NM_001244580.1; = p.D2511N on NM_003496.3) | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs752519925, COSV62856215; called by muse, mutect2, varscan2
- TSHZ1 | c.2029A>T p.N677Y (on ENST00000580243 / NM_001308210.2; = p.N632Y on NM_005786.6) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV59018704; called by muse, mutect2, varscan2
- TSHZ1 | c.2462T>G p.V821G (on ENST00000580243 / NM_001308210.2; = p.V776G on NM_005786.6) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59018740; called by muse, mutect2, varscan2
- TSNARE1 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV56185401; called by muse, mutect2, varscan2
- TSPO2 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55109368, COSV55112466; called by muse, mutect2, varscan2
- TTN | c.63349G>A p.D21117N (on ENST00000591111; = p.D13693N on NM_003319.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | PolyPhen possibly damaging (0.864); catalogued as rs397517675, COSV60012159, COSV60223415; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.31561C>T p.P10521S (on ENST00000591111; = p.P9594S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | PolyPhen benign (0.055); catalogued as COSV100616383, COSV60405654; called by muse, mutect2
- UBN1 | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs772390514, COSV52173945; called by muse, mutect2, varscan2
- UBQLN3 | c.1109G>A p.S370N | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV61164881, COSV61166242; called by muse, mutect2, varscan2
- UBXN2B | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV68309993; called by muse, mutect2, varscan2
- UGT1A4 | c.7A>T p.R3* | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | catalogued as rs1411325211; called by muse, mutect2, varscan2
- UGT2A3 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as rs267600216, COSV52359885, COSV52360393; called by muse, mutect2, varscan2
- UGT2B15 | c.290G>A p.W97* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as rs759917429, COSV57737271; called by muse, mutect2, varscan2
- UNC13C | c.5306T>C p.I1769T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as COSV52913948; called by muse, mutect2, varscan2
- UNC5C | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV71662744; called by muse, mutect2, varscan2
- UROC1 | c.1832G>A p.G611D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52030598; called by muse, mutect2, varscan2
- USF3 | c.6391C>T p.P2131S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57078242; called by muse, mutect2, varscan2
- USH2A | c.11410C>T p.P3804S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56376898; called by muse, mutect2, varscan2
- USHBP1 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.751); catalogued as COSV53102986; called by muse, mutect2, varscan2
- USP21 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs749117248, COSV57088495; called by muse, mutect2, varscan2
- VIPR1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs769482985, COSV57298969; called by muse, mutect2, varscan2
- WASF2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.052); catalogued as rs267598535, COSV71006895; called by muse, mutect2, varscan2
- WASF3 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58972839; called by muse, mutect2, varscan2
- WEE2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 118/234 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV66879183; called by muse, mutect2, varscan2
- WWC1 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV54659837; called by muse, mutect2, varscan2
- XIRP1 | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs145488377; called by muse, mutect2, varscan2
- XIRP2 | c.598G>A p.E200K (on ENST00000628543; = p.E375K on NM_152381.6) | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV54698146; called by muse, mutect2, varscan2
- XIRP2 | c.2311A>C p.K771Q (on ENST00000628543; = p.K946Q on NM_152381.6) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV54740332; called by muse, mutect2, varscan2
- XIRP2 | c.5480G>A p.G1827E (on ENST00000628543; = p.G2002E on NM_152381.6) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV54740343; called by muse, mutect2, varscan2
- XKR3 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV58888166; called by muse, mutect2, varscan2
- XPOT | c.2782C>T p.Q928* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV60348911; called by muse, mutect2, varscan2
- ZBP1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs748618471, COSV59065136; called by muse, mutect2, varscan2
- ZBTB39 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55631260; called by muse, mutect2, varscan2
- ZEB2 | c.3052A>G p.K1018E | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57968122; called by muse, mutect2, varscan2
- ZFP37 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV65289053; called by muse, mutect2, varscan2
- ZFP90 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV68051458; called by muse, mutect2, varscan2
- ZFPM2 | c.2716G>A p.D906N | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV65875469; called by muse, varscan2
- ZFPM2 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.416); catalogued as rs749656717, COSV65872951; called by muse, varscan2
- ZNF215 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53495565; called by muse, mutect2, varscan2
- ZNF226 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV56198191; called by muse, mutect2, varscan2
- ZNF229 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV52165788; called by muse, mutect2, varscan2
- ZNF230 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV101432003, COSV71273815; called by muse, mutect2, varscan2
- ZNF347 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 29/74 reads (39%) | catalogued as rs768177572, COSV100498453, COSV61971125, COSV61971382; called by muse, mutect2, varscan2
- ZNF347 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61971387; called by muse, mutect2, varscan2
- ZNF407 | c.5944C>T p.P1982S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV55274235; called by muse, mutect2, varscan2
- ZNF506 | c.572A>T p.Y191F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV71354838; called by muse, mutect2, varscan2
- ZNF585B | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.039); catalogued as rs552277190, COSV57215715; called by muse, mutect2, varscan2
- ZNF676 | c.638C>T p.S213F (on ENST00000650058; = p.S181F on NM_001001411.3) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.092); catalogued as COSV68093045, COSV68093432; called by muse, mutect2, varscan2
- ZNF681 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV68076006; called by muse, mutect2
- ZNF695 | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.391); catalogued as rs775346703, COSV100377213, COSV60585127; called by muse, mutect2, varscan2
- ZNF781 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476560461, COSV62203202; called by muse, mutect2, varscan2
- ZNF808 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs767562811, COSV63122071; called by muse, mutect2, varscan2
- ZNF98 | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63335931; called by muse, mutect2, varscan2
- ZSCAN1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs1165702289; called by muse, mutect2, varscan2
- ZSCAN20 | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63684912; called by muse, mutect2, varscan2
- ACACA | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AKAP13 | c.5627C>T p.S1876F (on ENST00000394518 / NM_007200.5; = p.S1880F on NM_006738.6) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKR1C8P | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKR7A3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ARMC4 | c.2673del p.K891Nfs*18 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel*, varscan2
- BTN2A3P | n.1065C>T | Splice Region (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- COL2A1 | c.2960G>A p.G987E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL2A1 | c.2959G>A p.G987R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A6 | c.3148C>T p.P1050S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DLL4 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EXOSC7 | c.663_665delinsTT p.S222Cfs*9 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | called by pindel, varscan2*
- FAM71A | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.683); called by muse, mutect2
- GTF2IRD2B | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | called by mutect2, varscan2
- HOXD8 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.298); called by muse, mutect2
- IFRD2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- IGHG3 | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IGHV3-33 | c.250A>T p.K84* | Nonsense Mutation (SNP) | VAF 52/92 reads (57%) | called by muse, mutect2, varscan2
- INPP5D | c.1557G>A p.G519= (on ENST00000445964 / NM_001017915.3; = p.G518= on NM_005541.5) | Splice Region (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- KMT2B | c.4943G>A p.G1648D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPKBP1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MAPKBP1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- MRC1 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.019); called by mutect2, varscan2
- MUC16 | c.15616G>A p.D5206N | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2
- OR2G3 | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2M2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCM1 | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCM1 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEBP4 | c.221G>A p.W74* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- PKHD1 | c.10796A>T p.H3599L | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRAMEF7 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- SBK1 | c.34del p.R12Afs*3 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- TNFRSF18 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TRAPPC10 | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- UNK | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- XRN1 | c.4537C>T p.P1513S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AADACL4 | c.150C>T p.F50= | Silent (SNP) | VAF 44/178 reads (25%) | catalogued as rs267597966, COSV66106324; called by muse, mutect2, varscan2
- ABCB5 | c.2253C>T p.F751= (on ENST00000404938 / NM_001163941.2; = p.F306= on NM_178559.6) | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as rs1378174253, COSV51722855; called by muse, mutect2, varscan2
- ABCC6 | c.3420C>T p.F1140= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV52747145, COSV52748609; called by muse, mutect2, varscan2
- ABT1 | c.78G>A p.E26= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV51293863; called by muse, mutect2
- AC008676.3 | c.540G>A p.L180= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV56638384; called by muse, mutect2, varscan2
- ACTRT2 | c.792C>T p.F264= | Silent (SNP) | VAF 59/124 reads (48%) | catalogued as rs774983376, COSV65759185; called by muse, mutect2, varscan2
- ADAM21 | c.84C>T p.Y28= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs1340586081, COSV50814665; called by muse, mutect2, varscan2
- ADAM21 | c.1371C>T p.F457= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as COSV50814786; called by muse, mutect2, varscan2
- ADAM7 | c.765A>G p.E255= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV51547722; called by muse, mutect2, varscan2
- ADAMTS10 | c.2256G>A p.Q752= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as COSV54360401, COSV99547516; called by muse, mutect2
- ADGRE1 | c.384C>T p.F128= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV51681788; called by muse, mutect2, varscan2
- ADGRG3 | c.1474T>C p.L492= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs755766595, COSV59652992; called by muse, mutect2, varscan2
- ADGRG4 | c.8166C>T p.T2722= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs1473004445, COSV54969358; called by muse, mutect2, varscan2
- AGMAT | c.354C>T p.S118= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as COSV65435865; called by muse, mutect2, varscan2
- AHCY | c.450C>T p.I150= | Silent (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- AKAP13 | c.5628C>T p.S1876= (on ENST00000394518 / NM_007200.5; = p.S1880= on NM_006738.6) | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs764970319; called by muse, mutect2, varscan2
- AKR7A3 | c.954C>T p.A318= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100853832; called by muse, mutect2, varscan2
- ANK2 | c.10875G>A p.G3625= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV52193707; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2271C>T p.S757= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs1476193342; called by muse, mutect2, varscan2
- ANKS1B | c.1023G>A p.K341= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV61381694; called by muse, mutect2, varscan2
- AP002748.5 | c.684C>T p.S228= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV59152605; called by muse, mutect2, varscan2
- AREL1 | c.2448T>C p.G816= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV62668394; called by muse, mutect2, varscan2
- ARL2 | c.324C>T p.S108= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs554217695; called by muse, mutect2, varscan2
- ARL2 | c.325C>T p.L109= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- ATP8A1 | c.3243C>G p.V1081= | Silent (SNP) | VAF 51/144 reads (35%) | catalogued as COSV52550596; called by muse, mutect2, varscan2
- BTBD16 | c.801C>T p.T267= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV53267703; called by muse, mutect2, varscan2
- C11orf53 | c.540C>T p.T180= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV54722831; called by muse, mutect2, varscan2
- C1QTNF9B | c.351G>A p.E117= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV65944709; called by muse, mutect2, varscan2
- C2orf16 | c.2670C>T p.S890= | Silent (SNP) | VAF 57/123 reads (46%) | catalogued as COSV62679002; called by muse, mutect2, varscan2
- C4B | c.3369G>A p.V1123= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as rs371168662; called by muse, mutect2, varscan2
- C4BPA | c.468C>T p.V156= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV65537911; called by mutect2, varscan2
- C4BPA | c.1677C>T p.L559= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV65537914; called by muse, mutect2, varscan2
- CACNA1A | c.1926C>T p.F642= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs772832553, COSV64191195; called by muse, mutect2, varscan2
- CAPN12 | c.984C>T p.F328= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs753915944, COSV61019032; called by muse, mutect2
- CASR | c.288G>A p.R96= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs375151193, COSV56141138; ClinVar: likely benign; called by muse, mutect2, varscan2
- CASR | c.993G>A p.R331= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV56142169; called by muse, mutect2, varscan2
- CCDC114 | c.1791C>T p.G597= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV59559149; called by muse, mutect2, varscan2
- CCDC57 | c.732C>T p.S244= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV66436258; called by muse, mutect2
- CCNJL | c.762C>T p.V254= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1274479276, COSV57447514; called by muse, mutect2, varscan2
- CCR5 | c.360C>T p.I120= | Silent (SNP) | VAF 76/255 reads (30%) | catalogued as rs200108729, COSV52753246; called by muse, mutect2, varscan2
- CCR6 | c.159C>T p.Y53= | Silent (SNP) | VAF 56/80 reads (70%) | catalogued as COSV59476476; called by muse, mutect2, varscan2
- CDH2 | c.306C>T p.F102= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as COSV52289500; called by muse, mutect2, varscan2
- CDH3 | c.891C>T p.T297= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV50580739; called by muse, mutect2, varscan2
- CDK15 | c.528C>T p.F176= (on ENST00000652192 / NM_001366386.2; = p.F125= on NM_139158.2) | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as rs779480760, COSV53635436, COSV53639513; called by muse, mutect2, varscan2
- CEACAM20 | c.879C>T p.P293= | Silent (SNP) | VAF 155/495 reads (31%) | catalogued as COSV57603624; called by muse, mutect2, varscan2
- CELSR3 | c.7524C>T p.S2508= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV51175624; called by muse, mutect2, varscan2
- CEP164 | c.3660C>T p.T1220= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV54047350; called by muse, mutect2, varscan2
- CFAP47 | c.783C>T p.F261= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV52893072; called by muse, mutect2, varscan2
- CFAP57 | c.573C>T p.S191= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV65264831; called by muse, mutect2, varscan2
- CFLAR | c.1116C>T p.L372= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV58582486; called by muse, mutect2, varscan2
- CGNL1 | c.888C>T p.S296= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV55577002; called by muse, mutect2, varscan2
- CHRNG | c.1119G>A p.R373= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as COSV67316133; called by muse, mutect2, varscan2
- CHST8 | c.1032C>T p.F344= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52864140; called by muse, mutect2, varscan2
- CHUK | c.435A>G p.L145= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV64918878; called by muse, mutect2, varscan2
- CKAP2L | c.591G>A p.R197= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV56696639; called by muse, mutect2, varscan2
- CLSPN | c.2985G>A p.E995= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV52058038; called by muse, mutect2, varscan2
- COL11A2 | c.579C>T p.A193= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs201054429, COSV59503673; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.4011G>A p.G1337= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV52871446; called by muse, mutect2, varscan2
- COL2A1 | c.831C>T p.F277= | Silent (SNP) | VAF 65/232 reads (28%) | catalogued as rs1426770511, COSV100475419, COSV61535352; called by muse, mutect2, varscan2
- COL5A1 | c.1704G>A p.G568= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs753248474, COSV65676264; called by muse, mutect2, varscan2
- COPA | c.1098C>T p.F366= | Silent (SNP) | VAF 102/135 reads (76%) | catalogued as COSV54101151; called by muse, mutect2, varscan2
- CPNE4 | c.51C>T p.I17= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV70201508; called by muse, mutect2, varscan2
- CSMD1 | c.8655C>T p.S2885= (on ENST00000520002; = p.S2884= on NM_033225.6) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs370529448, COSV59396787; called by muse, mutect2, varscan2
- CTNND2 | c.3642G>A p.T1214= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs765387726, COSV58891324; called by muse, mutect2, varscan2
- CUX1 | c.3000C>T p.I1000= | Silent (SNP) | VAF 37/161 reads (23%) | catalogued as COSV52919039; called by muse, mutect2, varscan2
- CYP11B2 | c.699C>T p.S233= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV59998287; called by muse, mutect2, varscan2
- CYP4A22 | c.933C>T p.L311= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as COSV53742958; called by muse, mutect2, varscan2
- CYP4F3 | c.30C>T p.G10= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs769468302, COSV55414330; called by muse, mutect2, varscan2
- DCAF12L1 | c.1350C>T p.L450= | Silent (SNP) | VAF 40/48 reads (83%) | catalogued as rs1481312541, COSV64421425, COSV64422505; called by muse, mutect2, varscan2
- DCAF4 | c.438C>T p.A146= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV62320715; called by muse, mutect2
- DCC | c.1470A>T p.G490= | Silent (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- DIP2B | c.3822C>T p.I1274= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs766420539, COSV56593657; called by muse, mutect2, varscan2
- DLL3 | c.816C>T p.V272= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV52694776; called by muse, mutect2, varscan2
- DMP1 | c.795G>A p.R265= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV56822563; called by muse, mutect2, varscan2
- DNAH10 | c.5691C>T p.T1897= (on ENST00000409039; = p.T1836= on NM_207437.3) | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as rs202158921; called by muse, mutect2, varscan2
- DNAH2 | c.3667C>T p.L1223= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV66721463; called by muse, mutect2, varscan2
- DNAH3 | c.12273C>T p.S4091= | Silent (SNP) | VAF 59/163 reads (36%) | catalogued as COSV54558165; called by muse, mutect2, varscan2
- DNAH5 | c.11514G>A p.E3838= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV54257804; called by muse, mutect2, varscan2
- DNAH5 | c.4557C>T p.I1519= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs868639381, COSV54219679; called by muse, mutect2, varscan2
- DNAH8 | c.9795G>A p.G3265= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs768779771, COSV59439642, COSV59447847; called by muse, mutect2, varscan2
- DOCK11 | c.2955C>T p.P985= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as COSV52249393, COSV99354062; called by muse, mutect2, varscan2
- DOCK6 | c.4065G>A p.K1355= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53923738; called by muse, mutect2
- DOP1B | c.1137A>G p.Q379= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as rs772310594, COSV67696928; called by muse, varscan2
- DPH6 | c.207C>T p.L69= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV56620493; called by muse, mutect2, varscan2
- DROSHA | c.3370C>T p.L1124= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV60784062; called by muse, mutect2, varscan2
- EDAR | c.978G>A p.R326= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs749981923, COSV51502766; called by muse, mutect2, varscan2
- EIF3L | c.999C>T p.I333= | Silent (SNP) | VAF 82/205 reads (40%) | catalogued as rs758819456, COSV67740258; called by muse, mutect2, varscan2
- EMILIN3 | c.519G>A p.R173= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as COSV60035794; called by muse, mutect2, varscan2
- EML2 | c.594G>T p.V198= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV55604810; called by muse, mutect2, varscan2
- EPC2 | c.789C>T p.H263= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs748301230; called by muse, mutect2, varscan2
- EPHB1 | c.1014C>T p.I338= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs113043235, COSV67673594; called by muse, mutect2, varscan2
- EXOC6 | c.1845T>A p.L615= | Silent (SNP) | VAF 219/491 reads (45%) | catalogued as COSV53333859; called by muse, mutect2, varscan2
- FAM151A | c.426G>A p.L142= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV56366699; called by muse, mutect2, varscan2
- FANCD2 | c.1998G>A p.V666= | Silent (SNP) | VAF 46/316 reads (15%) | catalogued as rs1344382468, COSV55048031; called by muse, varscan2
- FAT2 | c.2172C>T p.V724= | Silent (SNP) | VAF 70/135 reads (52%) | catalogued as COSV55831609; called by muse, mutect2, varscan2
- FCGBP | c.8091G>A p.G2697= | Silent (SNP) | VAF 50/253 reads (20%) | catalogued as rs1320408824, COSV55458174; called by muse, mutect2, varscan2
- FLNC | c.1599C>T p.F533= | Silent (SNP) | VAF 53/221 reads (24%) | catalogued as rs768072902, COSV57953887; called by muse, mutect2, varscan2
- GABRA2 | c.1224G>A p.K408= | Silent (SNP) | VAF 92/241 reads (38%) | catalogued as rs145736784, COSV62916598, COSV62918140; called by muse, mutect2, varscan2
- GABRB2 | c.945C>T p.F315= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs79319310, COSV50936521; called by muse, mutect2, varscan2
- GALNTL5 | c.1251G>A p.R417= | Silent (SNP) | VAF 49/79 reads (62%) | catalogued as COSV67180569, COSV67181471; called by muse, mutect2, varscan2
- GJA10 | c.1434A>C p.T478= | Silent (SNP) | VAF 46/69 reads (67%) | catalogued as COSV65356558; called by muse, mutect2, varscan2
- GK2 | c.744G>A p.L248= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as rs761068317, COSV62628677; called by muse, mutect2, varscan2
- GOLGB1 | c.8487C>T p.N2829= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV61472292; called by muse, mutect2, varscan2
- GPBP1L1 | c.156T>A p.G52= | Silent (SNP) | VAF 14/157 reads (9%) | catalogued as COSV51967591, COSV51973970; called by muse, mutect2
- GPR158 | c.2400G>A p.G800= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs1341254449, COSV66266498; called by muse, mutect2, varscan2
- GPRIN1 | c.1563C>T p.P521= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs1195202301, COSV56146429; called by muse, mutect2, varscan2
- GRIA1 | c.558G>A p.R186= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs773431386, COSV53628618; called by muse, mutect2, varscan2
- GRIN2A | c.3102G>A p.R1034= | Silent (SNP) | VAF 73/210 reads (35%) | catalogued as COSV58056949; called by muse, mutect2, varscan2
- GUCY1A2 | c.1134C>T p.V378= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV56505306; called by muse, mutect2, varscan2
- HNRNPA1 | c.786A>G p.G262= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV52939241; called by muse, mutect2, varscan2
- HYDIN | c.13905G>A p.V4635= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- IGHG3 | c.519C>T p.F173= | Silent (SNP) | VAF 35/51 reads (69%) | catalogued as rs587749375; called by muse, mutect2, varscan2
- IGSF21 | c.201C>T p.T67= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV52146377; called by muse, mutect2, varscan2
- IL9R | c.963G>A p.G321= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs1375382643, COSV54902613; called by muse, mutect2, varscan2
- INHBA | c.1257C>T p.I419= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as rs755611862, COSV54219452, COSV54219664; called by muse, varscan2
- ITGAX | c.3009C>T p.I1003= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs371222071; called by muse, mutect2, varscan2
- KAT6A | c.4008C>T p.P1336= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as rs1310048868, COSV55912759; called by muse, mutect2, varscan2
- KIF18B | c.2400C>T p.A800= (on ENST00000593135 / NM_001265577.2; = p.A812= on NM_001264573.2) | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1408621936, COSV59276840; called by muse, mutect2
- KIF26B | c.2451C>T p.S817= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as rs773441087, COSV63654217; called by muse, mutect2, varscan2
- KIF2B | c.141G>C p.T47= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV52127788, COSV52128264, COSV52136589; called by muse, mutect2, varscan2
- KLHL2 | c.954G>A p.K318= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as COSV56983862; called by muse, mutect2, varscan2
- LCMT1 | c.516C>T p.L172= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- LILRA2 | c.600G>A p.S200= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as rs141931276; called by muse, varscan2
- LPAR1 | c.240C>T p.F80= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs763201537, COSV62692276; called by muse, mutect2, varscan2
- LRRC17 | c.180C>T p.L60= | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as COSV50864647; called by muse, mutect2, varscan2
- LTBP2 | c.834C>T p.T278= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as rs1238079155, COSV56215143; called by muse, mutect2, varscan2
- MAN2B1 | c.720G>A p.R240= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- MARCO | c.243C>T p.F81= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as rs75633112, COSV59053927; called by muse, mutect2, varscan2
- MAST1 | c.2103C>T p.I701= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52256731; called by muse, mutect2, varscan2
- MB | c.18G>A p.G6= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs1290764467, COSV63094638; called by muse, mutect2, varscan2
- MED16 | c.1173C>T p.V391= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV54130599; called by muse, mutect2, varscan2
- MON2 | c.1602G>A p.Q534= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV54816797; called by muse, mutect2, varscan2
- MOXD1 | c.1341G>A p.T447= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs202102392, COSV60945003; called by muse, mutect2, varscan2
- MRGPRX2 | c.733C>T p.L245= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV61675089; called by muse, mutect2, varscan2
- MS4A10 | c.318G>A p.G106= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as COSV57634382; called by muse, mutect2, varscan2
- MSLN | c.1512C>T p.I504= (on ENST00000382862 / NM_013404.4; = p.I496= on NM_005823.6) | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV53507195; called by muse, mutect2, varscan2
- MST1R | c.882G>A p.R294= | Silent (SNP) | VAF 49/123 reads (40%) | catalogued as COSV56575069; called by muse, mutect2, varscan2
- MUC16 | c.15615G>A p.T5205= | Silent (SNP) | VAF 48/170 reads (28%) | catalogued as rs1250320746, COSV101200117; called by muse, mutect2
- MUC16 | c.12459G>A p.V4153= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV67500891; called by muse, mutect2, varscan2
- MUC5B | c.13588C>T p.L4530= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as rs756859099, COSV71596558; called by muse, mutect2, varscan2
- MYO15A | c.777C>T p.P259= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs774662522, COSV52768226, COSV99231785; called by muse, mutect2, varscan2
- MYO5A | c.1551A>G p.K517= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV62565816; called by muse, mutect2, varscan2
- NAGLU | c.1644C>T p.P548= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV56796499; called by muse, mutect2, varscan2
- NCOR2 | c.6105C>T p.L2035= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV62297690; called by muse, mutect2, varscan2
- NEB | c.15825G>A p.G5275= | Silent (SNP) | VAF 58/202 reads (29%) | catalogued as CM144550, COSV51466943; called by muse, mutect2, varscan2
- NIPAL4 | c.903G>A p.V301= | Silent (SNP) | VAF 84/155 reads (54%) | catalogued as COSV57441110; called by muse, mutect2, varscan2
- NLRP4 | c.69C>T p.F23= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV56725080; called by muse, mutect2, varscan2
- NLRP5 | c.2232C>T p.F744= | Silent (SNP) | VAF 82/231 reads (35%) | catalogued as COSV66767990; called by muse, mutect2, varscan2
- NMNAT3 | c.234C>T p.I78= (on ENST00000296202 / NM_001320512.1; = p.I41= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV56156780, COSV56159911; called by muse, mutect2, varscan2
- NOL11 | c.639G>A p.R213= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV53526036; called by muse, mutect2, varscan2
- NPSR1 | c.762G>A p.G254= | Silent (SNP) | VAF 43/82 reads (52%) | catalogued as COSV100705958, COSV62208531; called by muse, mutect2, varscan2
- NWD1 | c.1641C>G p.A547= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV60353579; called by muse, mutect2, varscan2
- NXNL1 | c.300C>T p.F100= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV57325247, COSV57325473; called by muse, mutect2, varscan2
- OBSCN | c.15708C>T p.F5236= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV52841672; called by muse, mutect2, varscan2
- OR14K1 | c.12G>A p.Q4= | Silent (SNP) | VAF 75/97 reads (77%) | catalogued as COSV99315559; called by muse, mutect2, varscan2
- OR1L8 | c.321C>T p.A107= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV59187629; called by muse, mutect2, varscan2
- OR2G3 | c.393C>T p.H131= | Silent (SNP) | VAF 41/224 reads (18%) | called by muse, mutect2, varscan2
- OR2L8 | c.102C>T p.F34= | Silent (SNP) | VAF 221/282 reads (78%) | catalogued as COSV61727333; called by muse, mutect2, varscan2
- OR2Z1 | c.256C>T p.L86= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as COSV60693510; called by muse, mutect2, varscan2
- OR4X2 | c.105C>T p.F35= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as rs759467119, COSV56582630; called by muse, mutect2, varscan2
- OR51M1 | c.519C>T p.L173= | Silent (SNP) | VAF 97/225 reads (43%) | catalogued as rs923901224, COSV60785707; called by muse, mutect2, varscan2
- OR52N1 | c.135C>T p.F45= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs570634505, COSV57693354; called by muse, mutect2, varscan2
- OR5K4 | c.279C>T p.S93= | Silent (SNP) | VAF 77/244 reads (32%) | catalogued as COSV61583580; called by muse, mutect2, varscan2
- OR9I1 | c.849C>T p.P283= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV56927727; called by muse, mutect2, varscan2
- PARP4 | c.2586C>T p.P862= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs531124907; called by muse, mutect2, varscan2
- PCDHA13 | c.591G>A p.R197= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV56514859; called by muse, mutect2, varscan2
- PCDHA2 | c.270C>T p.I90= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as rs1474265282, COSV65367343; called by muse, mutect2, varscan2
- PCDHA4 | c.1344G>A p.V448= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV63547007; called by muse, mutect2
- PCDHAC2 | c.2247G>A p.R749= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1563386071, COSV53874217; called by muse, mutect2, varscan2
- PCDHB1 | c.534C>T p.F178= | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as COSV60633758; called by muse, mutect2, varscan2
- PCDHB11 | c.1755G>A p.L585= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100696990; called by muse, mutect2, varscan2
- PCDHB3 | c.36G>A p.R12= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV50640751; called by muse, mutect2, varscan2
124 further variants in this file (0 protein-altering or splice-affecting, 109 silent, 15 other) are not listed here.
